Somatic mutation profile of tumor specimen TCGA-CR-7374-01A (aliquot TCGA-CR-7374-01A-11D-2012-08) from TCGA case TCGA-CR-7374, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 67.2 years (24,558 days).
Specimen TCGA-CR-7374-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72b79c6e-3138-43bc-8b30-8f8e7e34fe22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7374-10A (Blood Derived Normal), aliquot TCGA-CR-7374-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d71d3873-c463-4dca-86d7-f6a4e3980d45

The open-access MAF lists 376 somatic variants for this specimen: 287 protein-altering or splice-affecting, 75 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 244, Silent 75, Nonsense Mutation 25, Frame Shift Del 6, RNA 5, Intron 5, Splice Site 4, In Frame Del 2, Translation Start Site 2, 3'UTR 2, 3'Flank 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1695+1G>A p.X565_splice | Splice Site (SNP) | VAF 13/30 reads (43%) | catalogued as rs587778857, CS051701, CS146442, COSV57297353, COSV57300949, COSV99925943; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1461590067, COSV66063776; called by muse, mutect2, varscan2
- ABCA10 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV99287798; called by muse, mutect2, varscan2
- ABCB4 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV99710934; called by muse, mutect2, varscan2
- ABCC8 | c.3388A>G p.T1130A | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as CM060773, COSV100217579; called by muse, mutect2, varscan2
- ACBD7 | c.195G>T p.G65= | Splice Region (SNP) | VAF 62/181 reads (34%) | catalogued as COSV100650435; called by muse, mutect2, varscan2
- ADAMTS3 | c.602A>T p.Y201F | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV99711735; called by muse, mutect2, varscan2
- ADGRB3 | c.4039C>A p.P1347T | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV99485486, COSV99486337; called by muse, mutect2, varscan2
- ADGRF5 | c.2182C>G p.L728V | Missense Mutation (SNP) | VAF 76/395 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99346126; called by muse, mutect2, varscan2
- ADGRL3 | c.2090G>A p.R697H (on ENST00000506720 / NM_001322402.2; = p.R629H on NM_015236.6) | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs921791162, COSV72231313; called by muse, mutect2, varscan2
- ALG11 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV101584371; called by muse, mutect2, varscan2
- ALS2 | c.4033C>G p.Q1345E | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99969792; called by muse, mutect2, varscan2
- AMER3 | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs748468661, COSV100366773; called by muse, mutect2, varscan2
- ANKRD11 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV56356970; called by muse, mutect2
- ANKRD30A | c.1601C>A p.P534Q (on ENST00000611781; = p.P478Q on NM_052997.2) | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100654155; called by muse, mutect2, varscan2
- ANKRD44 | c.2539G>T p.A847S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99985647; called by muse, mutect2, varscan2
- ANKRD53 | c.578G>T p.C193F | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99721496; called by muse, mutect2, varscan2
- ANKRD6 | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs926915572, COSV100330239; called by muse, mutect2, varscan2
- ANO10 | c.1637C>G p.S546* | Nonsense Mutation (SNP) | VAF 8/138 reads (6%) | catalogued as COSV99428817; called by muse, mutect2
- ANO9 | c.275C>G p.T92S | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.287); catalogued as COSV100241128, COSV60451601; called by muse, mutect2, varscan2
- ANXA7 | c.1123C>T p.Q375* (on ENST00000372919 / NM_001320880.2; = p.Q353* on NM_001156.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 109/470 reads (23%) | catalogued as COSV65824280; called by muse, mutect2, varscan2
- AOC1 | c.1937C>A p.P646Q | Missense Mutation (SNP) | VAF 86/166 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100710892, COSV62868041; called by muse, mutect2, varscan2
- AP002512.3 | c.681G>T p.M227I | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as COSV99688074; called by muse, mutect2, varscan2
- AP3B1 | c.3045G>T p.Q1015H | Missense Mutation (SNP) | VAF 78/115 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV99672113; called by muse, mutect2, varscan2
- AP3D1 | c.3079-1G>C p.X1027_splice | Splice Site (SNP) | VAF 18/75 reads (24%) | catalogued as COSV100642887, COSV61428537; called by muse, mutect2, varscan2
- ARHGAP15 | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as rs150643555; called by muse, mutect2, varscan2
- ARHGAP21 | c.3640C>T p.R1214* | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as rs149363020; called by muse, mutect2, varscan2
- ASXL3 | c.5576G>T p.C1859F | Missense Mutation (SNP) | VAF 19/627 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99325898; called by muse, mutect2
- ATP12A | c.537G>C p.M179I | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99518150; called by muse, mutect2, varscan2
- ATP2C2 | c.1676C>G p.S559C | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV99298449; called by muse, mutect2
- ATRX | c.5295C>G p.I1765M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100971216; called by muse, mutect2, varscan2
- BTN3A2 | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100709661; called by muse, mutect2, varscan2
- BUB1B | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99807162; called by muse, mutect2
- C20orf194 | c.830A>T p.H277L | Missense Mutation (SNP) | VAF 318/600 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as rs372819234, COSV99331235; called by muse, mutect2, varscan2
- C7orf33 | c.288G>T p.W96C | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.327); catalogued as COSV100188861; called by muse, mutect2, varscan2
- CAMTA2 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100772753; called by muse, mutect2, varscan2
- CASR | c.2071G>T p.G691C (on ENST00000490131; = p.G768C on NM_000388.4) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99949286; called by muse, mutect2, varscan2
- CASZ1 | c.2492C>G p.S831* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100681897, COSV59740993; called by muse, mutect2, varscan2
- CBL | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as COSV50645836, COSV50648890; called by muse, mutect2, varscan2
- CCDC18 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); catalogued as COSV100159824; called by muse, mutect2, varscan2
- CCL3L3 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 61/706 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1473476410; called by muse, mutect2
- CCN4 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV99137049, COSV99137289; called by muse, mutect2, varscan2
- CDH9 | c.1285C>A p.R429S | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV99145164, COSV99150623; called by muse, mutect2, varscan2
- CENPE | c.3913A>G p.M1305V | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs750498079, COSV99478679; called by muse, mutect2, varscan2
- CEP83 | c.118T>A p.L40I | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV100353073; called by muse, mutect2, varscan2
- CIC | c.2489C>A p.P830H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99360029; called by muse, mutect2, varscan2
- COL1A2 | c.3484A>C p.T1162P | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99800546; called by muse, mutect2, varscan2
- CPA4 | c.719A>C p.K240T | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99745236; called by muse, mutect2, varscan2
- CPSF2 | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 33/97 reads (34%) | catalogued as COSV100103037; called by muse, mutect2, varscan2
- CTAGE6 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.712); catalogued as COSV101417867; called by mutect2, varscan2
- CTNNA2 | c.2859C>A p.F953L (on ENST00000402739 / NM_001282597.3; = p.F905L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV100561611; called by muse, mutect2, varscan2
- CTNND2 | c.2803C>T p.R935* | Nonsense Mutation (SNP) | VAF 63/141 reads (45%) | catalogued as COSV58887770, COSV58902310; called by muse, mutect2, varscan2
- CTNND2 | c.1598C>A p.P533Q | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100479529; called by muse, mutect2, varscan2
- CUX1 | c.1509C>G p.I503M (on ENST00000437600 / NM_181500.4; = p.I505M on NM_001913.5) | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99476454; called by muse, mutect2, varscan2
- CYSLTR2 | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV56165948, COSV99935323; called by muse, mutect2, varscan2
- CYSLTR2 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV99935326; called by muse, mutect2, varscan2
- DBH | c.1674C>A p.F558L | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV101257061, COSV101257123; called by muse, mutect2, varscan2
- DENND5A | c.3762C>G p.I1254M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV100065057, COSV60236125; called by muse, mutect2
- DLG1 | c.1282G>C p.D428H | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs1202000734, COSV100015765; called by muse, mutect2
- DMP1 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV99218902; called by muse, mutect2, varscan2
- DMXL1 | c.8635G>C p.V2879L | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV100224546; called by muse, mutect2, varscan2
- DNAH10 | c.11540A>G p.D3847G (on ENST00000409039; = p.D3786G on NM_207437.3) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1159015189, COSV101292473; called by muse, mutect2, varscan2
- DNAH11 | c.3295T>C p.F1099L | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100180080, COSV60965995; called by muse, mutect2, varscan2
- DNAI1 | c.790A>G p.R264G | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV99647022; called by muse, mutect2, varscan2
- DYNC2H1 | c.3745G>C p.D1249H | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100518620, COSV100519289; called by muse, mutect2
- ELAVL4 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV100836844; called by muse, mutect2, varscan2
- ELP2 | c.2195T>G p.L732R | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV100627012; called by muse, mutect2, varscan2
- EPS8L2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781407969, COSV100585650; called by muse, mutect2, varscan2
- ERBB4 | c.674A>T p.Y225F | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV99624907; called by muse, mutect2, varscan2
- ESRRG | c.414C>G p.Y138* | Nonsense Mutation (SNP) | VAF 58/203 reads (29%) | catalogued as COSV100753587; called by muse, mutect2, varscan2
- EVI2B | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV100445594; called by muse, mutect2, varscan2
- F5 | c.3674C>A p.A1225D | Missense Mutation (SNP) | VAF 215/691 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100889193; called by muse, mutect2, varscan2
- FAAH2 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.346); catalogued as COSV100887399; called by muse, mutect2, varscan2
- FANCI | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.137); catalogued as COSV100168354; called by muse, mutect2, varscan2
- FBN1 | c.6215C>T p.S2072L | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as COSV100355983; called by muse, mutect2
- FES | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV100182931, COSV100183245; called by muse, mutect2
- FLG | c.11380C>T p.Q3794* | Nonsense Mutation (SNP) | VAF 360/1055 reads (34%) | catalogued as rs562201369, COSV100911910; called by muse, mutect2, varscan2
- FLNA | c.1127A>T p.K376M | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV100774981; called by muse, mutect2, varscan2
- FMN2 | c.2936C>A p.P979H | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV100146627; called by muse, mutect2, varscan2
- FMN2 | c.5087G>A p.R1696K | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV60461369; called by muse, mutect2, varscan2
- FOXG1 | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.392); catalogued as COSV100486980, COSV57395515; called by muse, mutect2, varscan2
- FOXK1 | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100195602; called by muse, mutect2
- FOXK1 | c.1783G>A p.G595R | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.851); catalogued as rs752595661, COSV100195605; called by muse, mutect2, varscan2
- FRMD4B | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV68330459; called by muse, mutect2, varscan2
- FRMPD2 | c.1627C>A p.P543T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV100564054; called by muse, mutect2, varscan2
- FST | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56815030, COSV99887367; called by muse, mutect2, varscan2
- GABRA1 | c.1151C>A p.P384Q | Missense Mutation (SNP) | VAF 87/205 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.187); catalogued as COSV50108949, COSV99196150; called by muse, mutect2, varscan2
- GADD45GIP1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.87); catalogued as rs373898905; called by muse, mutect2, varscan2
- GANC | c.2012G>T p.R671I | Missense Mutation (SNP) | VAF 43/126 reads (34%) | PolyPhen benign (0.139); catalogued as COSV100531125, COSV58810887; called by muse, mutect2, varscan2
- GCM1 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV99452545; called by muse, mutect2, varscan2
- GIMAP6 | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 22/557 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61033848; called by muse, mutect2
- GJD2 | c.572G>T p.R191M | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as COSV51747284, COSV99290830; called by muse, mutect2, varscan2
- GLI4 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100391145; called by muse, mutect2, varscan2
- GLMP | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV99828041; called by muse, mutect2, varscan2
- GRIA3 | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 102/213 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99991179; called by muse, mutect2, varscan2
- GTF2A2 | c.203G>T p.C68F | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99139478; called by muse, mutect2, varscan2
- H2AC21 | c.387C>A p.N129K | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1235244720, COSV100480076; called by muse, mutect2, varscan2
- H2BC18 | c.167C>A p.S56* | Nonsense Mutation (SNP) | VAF 163/568 reads (29%) | catalogued as COSV100516147; called by muse, mutect2, varscan2
- HBM | c.19C>A p.R7S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs1437861967, COSV100720796; called by muse, mutect2, varscan2
- HDLBP | c.1645C>A p.Q549K | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100190457, COSV100191452; called by muse, mutect2, varscan2
- HECTD4 | c.1844C>G p.S615* | Nonsense Mutation (SNP) | VAF 9/186 reads (5%) | catalogued as COSV100296156; called by muse, mutect2
- HERPUD2 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.388); catalogued as COSV100258057; called by muse, mutect2, varscan2
- HSPA4L | c.1696G>C p.D566H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99613424; called by muse, mutect2, varscan2
- HSPA4L | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99613430; called by muse, mutect2, varscan2
- HSPA4L | c.2080G>C p.E694Q | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99613432; called by muse, mutect2, varscan2
- HUWE1 | c.2422C>T p.L808F | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99473499; called by muse, mutect2
- IFT80 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100424992; called by muse, mutect2, varscan2
- INSM1 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100044604, COSV100044826, COSV59605187; called by muse, mutect2, varscan2
- ITPR1 | c.6664G>A p.E2222K (on ENST00000354582; = p.E2167K on NM_002222.7) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV100232522; called by muse, mutect2
- ITSN2 | c.1875G>C p.M625I | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100743961; called by muse, mutect2, varscan2
- KALRN | c.6812C>T p.A2271V (on ENST00000360013 / NM_001024660.4; = p.A574V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs753999093, COSV99360822; called by muse, mutect2, varscan2
- KANK1 | c.1735G>C p.D579H | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100620010; called by muse, mutect2, varscan2
- KANSL1L | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV55995945; called by muse, mutect2
- KCNV1 | c.1252C>T p.L418F | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52086788; called by muse, mutect2, varscan2
- KCTD10 | c.717G>T p.Q239H | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV99949360; called by muse, mutect2, varscan2
- KLK13 | c.98G>T p.S33I | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV99335401; called by muse, mutect2, varscan2
- KRT24 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 31/442 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1165603150, COSV99232119; called by muse, mutect2
- KRT25 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 93/442 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV100380009, COSV56445584; called by muse, varscan2
- KRT25 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 69/399 reads (17%) | catalogued as COSV100380010; called by muse, varscan2
- LBR | c.1189G>T p.V397L | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.377); catalogued as COSV99687586; called by muse, mutect2, varscan2
- LRIG1 | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 148/295 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV99834131; called by muse, mutect2, varscan2
- LRRTM3 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.267); catalogued as COSV63668993; called by muse, mutect2
- MALSU1 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51688170; called by muse, mutect2, varscan2
- MAP1B | c.7349G>A p.S2450N | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99702755; called by muse, mutect2
- MAP2K1 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.26); catalogued as rs1205783274, COSV100199479, COSV61071105, COSV99047871; called by muse, mutect2, varscan2
- MAP3K5 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 55/211 reads (26%) | catalogued as COSV100753117; called by muse, varscan2
- MAPK13 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.281); catalogued as COSV99275375; called by muse, mutect2, varscan2
- MARS1 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100007549; called by muse, mutect2
- MBTPS2 | c.245T>G p.F82C | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV100810822; called by muse, mutect2, varscan2
- MCCC1 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55610217, COSV99659967; called by muse, mutect2
- MCOLN3 | c.568C>G p.P190A | Missense Mutation (SNP) | VAF 115/248 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100352897; called by muse, mutect2, varscan2
- MCTP2 | c.1739G>T p.G580V | Missense Mutation (SNP) | VAF 84/391 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100537611; called by muse, mutect2, varscan2
- METTL16 | c.1414G>T p.G472* | Nonsense Mutation (SNP) | VAF 100/398 reads (25%) | catalogued as COSV99563657; called by muse, mutect2, varscan2
- MFGE8 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 36/271 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as rs145851768; called by muse, mutect2, varscan2
- MICALL2 | c.1586C>A p.S529Y | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as COSV52518281, COSV99876160; called by muse, mutect2
- MINDY2 | c.1814G>C p.R605P | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100376490, COSV100376520; called by muse, mutect2, varscan2
- MITD1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 111/399 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs144672860; called by muse, mutect2, varscan2
- MPZL1 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV100850393; called by muse, mutect2
- MRAP | c.79G>C p.D27H | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353308; called by muse, mutect2
- MRGPRX2 | c.614T>A p.L205Q | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100316801, COSV61673911; called by muse, mutect2, varscan2
- MROH2B | c.961C>A p.Q321K | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.844); catalogued as COSV101270843; called by muse, mutect2, varscan2
- MS4A14 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV100280592, COSV100280637; called by muse, mutect2
- MTCL1 | c.1631A>C p.Y544S (on ENST00000306329 / NM_001378206.1; = p.Y184S on NM_015210.4) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1247239475, COSV100095260; called by muse, mutect2
- MTUS2 | c.903A>T p.L301F | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV101462310; called by muse, mutect2, varscan2
- MUC16 | c.39983A>C p.N13328T | Missense Mutation (SNP) | VAF 39/463 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV101110002; called by muse, mutect2
- MUC17 | c.2997G>T p.E999D | Missense Mutation (SNP) | VAF 313/667 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.182); catalogued as COSV100074432; called by muse, mutect2, varscan2
- MYH4 | c.4179C>A p.A1393= | Splice Region (SNP) | VAF 86/267 reads (32%) | catalogued as COSV99701893; called by muse, mutect2, varscan2
- MYL1 | c.257C>G p.P86R | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100498751; called by muse, mutect2, varscan2
- MYO10 | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV101549896; called by muse, mutect2, varscan2
- MYO3B | c.2407C>A p.Q803K | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as COSV100511173; called by muse, mutect2, varscan2
- NAALADL2 | c.331A>T p.T111S | Missense Mutation (SNP) | VAF 59/296 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV101435785; called by muse, mutect2, varscan2
- NAALADL2 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV101458190; called by muse, mutect2, varscan2
- NAV3 | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs770984486, COSV57085751; called by muse, mutect2, varscan2
- NBEAL2 | c.7556C>G p.S2519* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99436978; called by muse, mutect2, varscan2
- NBEAL2 | c.7734C>G p.I2578M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99436105, COSV99436983; called by muse, mutect2, varscan2
- NELL1 | c.2133T>A p.H711Q | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100123492; called by muse, mutect2, varscan2
- NEXMIF | c.3688G>A p.A1230T | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV99281409; called by muse, mutect2, varscan2
- NF1 | c.1259A>T p.N420I | Missense Mutation (SNP) | VAF 159/257 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV100647853; called by muse, mutect2, varscan2
- NLRP12 | c.329C>G p.S110* | Nonsense Mutation (SNP) | VAF 16/154 reads (10%) | catalogued as COSV100145508, COSV100145597; called by muse, mutect2, varscan2
- NPAT | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV99586235; called by muse, mutect2
- NPY1R | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV56715737; called by muse, mutect2, varscan2
- NTSR2 | c.522G>T p.M174I | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100183978; called by muse, mutect2, varscan2
- NUDT12 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100048185; called by muse, mutect2, varscan2
- NUP107 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99971949; called by muse, mutect2, varscan2
- OIT3 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100468223; called by muse, mutect2, varscan2
- OR10X1 | c.204C>G p.D68E | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV100936695; called by muse, mutect2, varscan2
- OR13C4 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 82/148 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as COSV99470085, COSV99470246; called by muse, mutect2, varscan2
- OR2A25 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 137/312 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101376407; called by muse, mutect2, varscan2
- OR2AK2 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV100824224; called by muse, mutect2
- OR2C3 | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV100825756; called by muse, mutect2, varscan2
- OR2T27 | c.413G>C p.R138P | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV100788324, COSV61281501, COSV61283032; called by muse, mutect2, varscan2
- OR51S1 | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100437553; called by muse, mutect2, varscan2
- OR5K3 | c.24G>C p.L8F | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV67350166; called by muse, mutect2, varscan2
- OR5L2 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV101004372; called by muse, mutect2, varscan2
- OR6K6 | c.655G>A p.D219N (on ENST00000368144; = p.D195N on NM_001005184.1) | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100933676; called by muse, mutect2, varscan2
- OR8H2 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 90/397 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs773811836, COSV100542430, COSV57943654; called by muse, mutect2
- OR8K5 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100537271; called by muse, mutect2, varscan2
- OSBP2 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100213517; called by muse, mutect2, varscan2
- PABPC5 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV100442462, COSV100442605; called by muse, mutect2, varscan2
- PAK2 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 34/446 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.027); catalogued as COSV59080084; called by muse, mutect2
- PARD6A | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV99537916; called by muse, mutect2, varscan2
- PCCA | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 105/157 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV100887002, COSV100887122; called by muse, mutect2, varscan2
- PCDH15 | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100225190; called by muse, mutect2, varscan2
- PCDHAC2 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs148804197; called by muse, mutect2
- PCF11 | c.2402G>C p.G801A | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV100018947; called by muse, mutect2
- PDPN | c.364G>C p.E122Q (on ENST00000621990; = p.E198Q on NM_006474.4) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV99611702; called by muse, mutect2, varscan2
- PDS5B | c.1930C>G p.Q644E | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141013786, COSV100221307; called by muse, mutect2, varscan2
- PIGR | c.844G>T p.V282F | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100732580; called by muse, mutect2, varscan2
- PIK3CA | c.1003A>G p.R335G | Missense Mutation (SNP) | VAF 42/376 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV99841488; called by muse, mutect2, varscan2
- PLEKHH1 | c.904A>T p.R302W | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.699); catalogued as COSV100233393; called by muse, mutect2, varscan2
- PLXNB2 | c.4282A>T p.I1428F | Missense Mutation (SNP) | VAF 122/363 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100834209; called by muse, mutect2, varscan2
- POTEE | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.944); catalogued as rs1378035295, COSV100386415; called by muse, mutect2, varscan2
- POU2F2 | c.1198G>C p.V400L (on ENST00000526816 / NM_001207025.3; = p.V384L on NM_002698.5) | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.355); catalogued as COSV100657443; called by muse, mutect2
- PRAMEF17 | c.1345A>G p.R449G | Missense Mutation (SNP) | VAF 154/302 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV101068778; called by muse, mutect2, varscan2
- PREX2 | c.2273A>T p.Y758F | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99908948; called by muse, mutect2, varscan2
- PRTG | c.2617C>A p.R873S | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV66838745; called by muse, varscan2
- PTEN | c.44G>C p.R15T | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs398123324, COSV100910708, COSV64297317, COSV64299553; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN21 | c.215A>C p.Q72P | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100162325; called by muse, mutect2, varscan2
- PTPN22 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100703845; called by muse, mutect2, varscan2
- RABGEF1 | c.88C>G p.L30V (on ENST00000439720 / NM_001287061.2; = p.L17V on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/297 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53161776; called by muse, mutect2, varscan2
- RCOR1 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 26/359 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.628); catalogued as COSV99217693; called by muse, mutect2
- REG1A | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV52071180, COSV99286689; called by muse, mutect2, varscan2
- REG3A | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV59412281; called by muse, mutect2, varscan2
- RFX4 | c.1135C>T p.Q379* (on ENST00000392842 / NM_213594.3; = p.Q285* on NM_032491.6) | Nonsense Mutation (SNP) | VAF 54/162 reads (33%) | catalogued as COSV99985742, COSV99986161; called by muse, mutect2, varscan2
- RGS7 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 44/144 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.091); catalogued as COSV100777263; called by muse, mutect2, varscan2
- RHOBTB1 | c.1359G>T p.M453I | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV100558629; called by muse, mutect2, varscan2
- RIMS3 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as rs771445638, COSV65504913; called by muse, mutect2, varscan2
- RIT2 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56295210; called by muse, mutect2, varscan2
- RNF213 | c.10501G>C p.E3501Q | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.607); catalogued as COSV60401084; called by muse, mutect2
- RNPEPL1 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 86/164 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs754035762, COSV99549652; called by muse, mutect2, varscan2
- RPA1 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 71/110 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1238804059, COSV54610917, COSV99628219; called by muse, mutect2, varscan2
- RYR2 | c.13383G>T p.K4461N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.834); catalogued as COSV63718576; called by muse, mutect2, varscan2
- SAMHD1 | c.599A>G p.Q200R | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs758250759, COSV99484240; called by muse, mutect2, varscan2
- SDE2 | c.730A>G p.M244V | Missense Mutation (SNP) | VAF 95/312 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99682772; called by muse, mutect2, varscan2
- SEMA5A | c.2087G>T p.C696F | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774417996, COSV101228593; called by muse, mutect2, varscan2
- SEPHS2 | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101529339, COSV72100812; called by muse, mutect2, varscan2
- SLC14A1 | c.82A>G p.R28G | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100425168; called by muse, mutect2
- SLC35B2 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 96/311 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51492354; called by muse, mutect2, varscan2
- SLC35F4 | c.268C>T p.H90Y (on ENST00000339762 / NM_001352015.2; = p.H54Y on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.063); catalogued as COSV100334090; called by muse, mutect2, varscan2
- SLC4A4 | c.292G>C p.E98Q (on ENST00000264485 / NM_001098484.3; = p.E54Q on NM_003759.4) | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); catalogued as COSV99141084; called by muse, mutect2
- SLC4A7 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.477); catalogued as COSV99840136; called by muse, mutect2, varscan2
- SLC7A6OS | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.182); catalogued as COSV99546744; called by muse, mutect2
- SLITRK2 | c.2371C>T p.R791* | Nonsense Mutation (SNP) | VAF 101/214 reads (47%) | catalogued as COSV100158057; called by muse, mutect2, varscan2
- SMYD4 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as COSV100563158; called by muse, mutect2
- SPATA5 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99916078; called by muse, mutect2, varscan2
- STOML3 | c.11G>T p.R4M | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV65510008; called by muse, mutect2
- SUOX | c.149C>G p.S50C | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.41); catalogued as COSV99907164; called by muse, mutect2, varscan2
- SVIP | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.085); catalogued as COSV100829808; called by muse, mutect2, varscan2
- SYN2 | c.1038G>C p.Q346H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101413859; called by muse, mutect2
- TAP2 | c.1710C>G p.S570R | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV100886921; called by muse, mutect2, varscan2
- TBC1D15 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | catalogued as COSV59849681; called by muse, mutect2, varscan2
- TBC1D32 | c.2635G>T p.G879C | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99250898; called by muse, mutect2, varscan2
- TBCEL | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as COSV99412335; called by muse, mutect2, varscan2
- THAP12 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 48/159 reads (30%) | catalogued as COSV99473166; called by muse, mutect2, varscan2
- TIGIT | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV101048249; called by muse, mutect2, varscan2
- TIPIN | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56019546; called by muse, mutect2
- TLR7 | c.817T>G p.C273G | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101028053; called by muse, mutect2, varscan2
- TNMD | c.775C>A p.L259M | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100887904; called by muse, mutect2, varscan2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 80/155 reads (52%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- TRIM58 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 131/369 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775669996, COSV100825217, COSV63569216; called by muse, mutect2, varscan2
- TRIP6 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV99308032; called by muse, mutect2
- TRIT1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV100381642; called by muse, mutect2
- TRPM7 | c.2374C>T p.H792Y | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100540142; called by muse, mutect2, varscan2
- TSR2 | c.264+1G>T p.X88_splice | Splice Site (SNP) | VAF 51/182 reads (28%) | catalogued as COSV100911218; called by muse, mutect2, varscan2
- TTC13 | c.930G>C p.L310F | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100792910, COSV64169521; called by muse, mutect2, varscan2
- TTN | c.58789C>T p.R19597C (on ENST00000591111; = p.R12173C on NM_003319.4) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | PolyPhen probably damaging (0.998); catalogued as rs190432620, COSV60468678; called by muse, mutect2, varscan2
- TTN | c.49279C>G p.P16427A (on ENST00000591111; = p.P9003A on NM_003319.4) | Missense Mutation (SNP) | VAF 56/194 reads (29%) | PolyPhen probably damaging (0.997); catalogued as COSV100623136, COSV100632270; called by muse, mutect2, varscan2
- TYW1 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 68/390 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100658959; called by muse, mutect2, varscan2
- UBC | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV60060629; called by muse, mutect2
- UBR5 | c.1712G>T p.S571I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.228); catalogued as COSV99641814; called by muse, mutect2, varscan2
- UGP2 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 130/421 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100451709; called by muse, mutect2, varscan2
- UNC5D | c.2441A>G p.H814R | Missense Mutation (SNP) | VAF 98/223 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV99777584; called by muse, mutect2, varscan2
- USH2A | c.13120G>A p.V4374I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs749238147, COSV100239485; called by muse, mutect2, varscan2
- USH2A | c.8396del p.G2799Vfs*31 | Frame Shift Del (DEL) | VAF 65/228 reads (29%) | catalogued as COSV100237517; called by mutect2, pindel, varscan2
- USP54 | c.2762C>G p.S921C | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as rs1018074632, COSV100357527; called by muse, mutect2, varscan2
- USP8 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs114434131, COSV100209163; called by muse, mutect2, varscan2
- USP9X | c.5083G>T p.D1695Y | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100199874; called by muse, mutect2, varscan2
- UTP20 | c.5605C>G p.L1869V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99882201; called by muse, mutect2, varscan2
- VIRMA | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99887519; called by muse, mutect2, varscan2
- WDR47 | c.1643C>G p.S548* (on ENST00000369962 / NM_001142551.2; = p.S549* on NM_014969.5) | Nonsense Mutation (SNP) | VAF 38/282 reads (13%) | catalogued as COSV100728409; called by muse, mutect2, varscan2
- XIRP2 | c.5336C>A p.A1779E (on ENST00000628543; = p.A1954E on NM_152381.6) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99745792; called by muse, mutect2, varscan2
- YME1L1 | c.356G>A p.R119K (on ENST00000326799 / NM_139312.3; = p.R62K on NM_014263.4) | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100463992; called by muse, mutect2, varscan2
- YTHDF3 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV101572417; called by muse, mutect2, varscan2
- ZBTB22 | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as COSV56472451, COSV99802452; called by muse, mutect2
- ZBTB25 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 150/452 reads (33%) | catalogued as COSV101170744; called by muse, mutect2, varscan2
- ZFP2 | c.322A>T p.S108C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV100797100; called by muse, mutect2, varscan2
- ZMAT1 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100858887; called by muse, mutect2
- ZMYND10 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1283608412, COSV99205627; called by muse, mutect2, varscan2
- ZNF14 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.572); catalogued as COSV100694110; called by muse, mutect2, varscan2
- ZNF385B | c.1273A>G p.K425E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100416271; called by muse, mutect2
- ZNF512B | c.2469G>C p.R823S | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV99412514; called by muse, mutect2
- ZNF615 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100943902; called by muse, mutect2
- ZNF804A | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100169329; called by muse, mutect2, varscan2
- ZNF836 | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100441134; called by muse, mutect2, varscan2
- ZNF836 | c.1510G>T p.G504C | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100440649; called by muse, mutect2, varscan2
- ZP2 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1419095696, COSV99559690; called by muse, mutect2, varscan2
- ATXN3 | c.237del p.I80* | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | called by mutect2, pindel, varscan2
- COPA | c.2477-15_2481del p.X826_splice | Splice Site (DEL) | VAF 32/132 reads (24%) | called by mutect2, pindel
- CPSF7 | c.1174_1179del p.L392_I393del (on ENST00000394888 / NM_001136040.4; = p.L435_I436del on NM_024811.4) | In Frame Del (DEL) | VAF 30/100 reads (30%) | called by mutect2, pindel, varscan2
- FRMPD3 | c.1882dup p.R628Pfs*12 | Frame Shift Ins (INS) | VAF 32/76 reads (42%) | called by mutect2, pindel, varscan2
- JTB | c.19_36del p.R7_Q12del | In Frame Del (DEL) | VAF 30/174 reads (17%) | called by mutect2, pindel
- ME3 | c.1758_1761del p.F587Hfs*12 | Frame Shift Del (DEL) | VAF 51/201 reads (25%) | called by mutect2, pindel, varscan2
- MROH1 | c.2701G>C p.E901Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- NR1H4 | c.1064del p.P355Rfs*22 (on ENST00000551379 / NM_001206993.2; = p.P341Rfs*22 on NM_005123.4) | Frame Shift Del (DEL) | VAF 24/107 reads (22%) | called by mutect2, pindel, varscan2
- SPTY2D1 | c.1523dup p.N508Kfs*18 | Frame Shift Ins (INS) | VAF 28/102 reads (27%) | called by mutect2, pindel, varscan2
- SRSF5 | c.784del p.R262Dfs*14 | Frame Shift Del (DEL) | VAF 63/395 reads (16%) | called by mutect2, pindel, varscan2
- WASHC2A | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ACOT12 | c.864C>T p.Y288= | Silent (SNP) | VAF 52/178 reads (29%) | catalogued as COSV100297073; called by muse, mutect2, varscan2
- ACSM2B | c.225G>A p.K75= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs761868480, COSV100313000; called by muse, mutect2, varscan2
- ADGRE1 | c.1917G>T p.L639= | Silent (SNP) | VAF 39/157 reads (25%) | catalogued as COSV51681960, COSV99165588; called by muse, mutect2, varscan2
- AGXT2 | c.237G>A p.T79= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as rs371190707; called by muse, mutect2, varscan2
- ANO3 | c.2799C>T p.Y933= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV99884551; called by muse, mutect2, varscan2
- APLP1 | c.558C>T p.L186= | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as rs1438088335, COSV99697831; called by muse, mutect2, varscan2
- BPIFB3 | c.735G>T p.L245= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV100972389; called by muse, mutect2, varscan2
- BRINP3 | c.1506G>A p.Q502= | Silent (SNP) | VAF 52/300 reads (17%) | catalogued as COSV66526976, COSV66528333; called by muse, mutect2, varscan2
- C12orf60 | c.504C>T p.T168= | Silent (SNP) | VAF 6/85 reads (7%) | catalogued as COSV99966949; called by muse, mutect2
- CA7 | c.219T>C p.N73= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV100623797; called by muse, mutect2, varscan2
- CD200R1 | c.681G>T p.L227= (on ENST00000471858 / NM_170780.3; = p.L250= on NM_138806.4) | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99867627; called by muse, mutect2, varscan2
- CD44 | c.1029G>A p.R343= | Silent (SNP) | VAF 43/190 reads (23%) | catalogued as COSV99555920; called by muse, mutect2, varscan2
- CDH3 | c.2037G>A p.K679= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV50557020, COSV99868872; called by muse, varscan2
- CLRN1 | c.237G>A p.R79= | Silent (SNP) | VAF 63/238 reads (26%) | catalogued as COSV100184603; called by muse, mutect2, varscan2
- COL25A1 | c.813G>A p.Q271= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV101211596; called by muse, mutect2, varscan2
- CSMD3 | c.2847G>C p.L949= (on ENST00000297405 / NM_001363185.1; = p.L845= on NM_052900.3) | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV99842527; called by muse, mutect2, varscan2
- DAXX | c.1533C>G p.G511= | Silent (SNP) | VAF 10/141 reads (7%) | catalogued as COSV99802454; called by muse, mutect2
- DBNL | c.219C>T p.N73= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs1562652054, COSV101289378; called by muse, mutect2, varscan2
- DNAH8 | c.2181C>T p.A727= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV100546615; called by muse, mutect2
- FABP1 | c.318C>T p.G106= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as rs773405309, COSV55559156; called by muse, mutect2, varscan2
- FAM135A | c.234T>C p.N78= (on ENST00000370479 / NM_001351599.1; = p.N35= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV99526415; called by muse, mutect2, varscan2
- FIBP | c.1094G>A p.*365= (on ENST00000338369 / NM_198897.2; = p.*358= on NM_004214.5) | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV57172150, COSV57172842; called by muse, mutect2, varscan2
- FLRT2 | c.342C>T p.L114= | Silent (SNP) | VAF 62/201 reads (31%) | catalogued as COSV100420776, COSV58136761; called by muse, mutect2, varscan2
- FMN2 | c.1194C>A p.P398= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as COSV60442956; called by muse, mutect2, varscan2
- FN1 | c.3102C>T p.T1034= | Silent (SNP) | VAF 61/116 reads (53%) | catalogued as rs1488485663, COSV100117791; called by muse, mutect2, varscan2
- GATA3 | c.411G>A p.S137= | Silent (SNP) | VAF 55/188 reads (29%) | catalogued as rs745734873, COSV60518006; called by muse, mutect2, varscan2
- GPM6A | c.525G>A p.L175= | Silent (SNP) | VAF 11/177 reads (6%) | catalogued as COSV99704924; called by muse, mutect2
- H3C4 | c.153G>A p.E51= | Silent (SNP) | VAF 58/185 reads (31%) | catalogued as COSV100587245; called by muse, mutect2, varscan2
- KAT6A | c.3657A>G p.L1219= | Silent (SNP) | VAF 57/127 reads (45%) | catalogued as COSV99705619; called by muse, mutect2, varscan2
- KCNJ11 | c.93G>A p.R31= | Silent (SNP) | VAF 14/199 reads (7%) | catalogued as rs1377294667, COSV100217578; called by muse, mutect2
- KCNN2 | c.1461C>T p.N487= (on ENST00000264773; = p.N699= on NM_021614.4) | Silent (SNP) | VAF 41/173 reads (24%) | catalogued as rs1341072233, COSV99300361; called by muse, mutect2, varscan2
- KIAA1109 | c.3378A>G p.K1126= | Silent (SNP) | VAF 53/111 reads (48%) | catalogued as COSV99169316; called by muse, mutect2, varscan2
- LILRA1 | c.642C>A p.L214= | Silent (SNP) | VAF 16/246 reads (7%) | catalogued as COSV99252053; called by muse, mutect2
- LRRC8E | c.2028A>T p.S676= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV100143074; called by muse, mutect2, varscan2
- LTF | c.1692G>T p.V564= | Silent (SNP) | VAF 68/99 reads (69%) | catalogued as COSV99210243; called by muse, mutect2, varscan2
- MAG | c.1407G>T p.V469= | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as COSV100727982; called by muse, mutect2, varscan2
- MIGA1 | c.648G>A p.L216= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as COSV100889795; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2475C>T p.D825= | Silent (SNP) | VAF 74/223 reads (33%) | catalogued as rs200988653, COSV56617140; called by muse, mutect2, varscan2
- MRPS11 | c.246G>A p.E82= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV100363783; called by muse, mutect2
- MUC16 | c.17862T>A p.A5954= | Silent (SNP) | VAF 51/157 reads (32%) | catalogued as COSV101200639; called by muse, mutect2, varscan2
- MYBPC3 | c.648C>A p.A216= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99920765; called by muse, varscan2
- MYO15A | c.10005C>T p.S3335= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs751601405, COSV99233828; called by muse, mutect2, varscan2
- NDUFV1 | c.816C>T p.G272= | Silent (SNP) | VAF 45/165 reads (27%) | catalogued as rs1334278588, COSV100295385; called by muse, mutect2, varscan2
- NSD3 | c.2784G>A p.S928= | Silent (SNP) | VAF 101/165 reads (61%) | catalogued as rs779779491, COSV100395541; called by muse, mutect2, varscan2
- NUP188 | c.5151G>A p.S1717= | Silent (SNP) | VAF 84/145 reads (58%) | catalogued as rs754094593, COSV65330209; called by muse, mutect2, varscan2
- PCDHB11 | c.1983C>G p.L661= | Silent (SNP) | VAF 11/200 reads (6%) | catalogued as rs782266124, COSV100697114; called by muse, mutect2
- PCDHGA10 | c.2260C>T p.L754= | Silent (SNP) | VAF 86/212 reads (41%) | catalogued as COSV99543280; called by muse, mutect2, varscan2
- PCDHGA2 | c.919C>T p.L307= | Silent (SNP) | VAF 15/285 reads (5%) | catalogued as COSV99543278; called by muse, mutect2
- PCP2 | c.85C>T p.L29= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99657293; called by muse, mutect2, varscan2
- PIKFYVE | c.2001C>T p.I667= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs776524286, COSV100011188, COSV52245237; called by muse, mutect2, varscan2
- PPARD | c.87C>G p.L29= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV100283255, COSV61101740; called by muse, mutect2, varscan2
- PRAMEF19 | c.1005C>T p.I335= | Silent (SNP) | VAF 260/683 reads (38%) | called by muse, mutect2, varscan2
- PUM1 | c.2775C>T p.V925= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99928652; called by muse, mutect2
- RASGRF1 | c.2770C>A p.R924= | Silent (SNP) | VAF 40/169 reads (24%) | catalogued as COSV101174674, COSV67250918; called by muse, mutect2, varscan2
- RFX1 | c.762A>T p.P254= | Silent (SNP) | VAF 41/175 reads (23%) | catalogued as COSV99586322; called by muse, mutect2, varscan2
- RHPN1 | c.1593G>A p.S531= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs768183720, COSV56649712; called by muse, mutect2, varscan2
- RNF40 | c.1761G>A p.E587= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100222248; called by muse, mutect2, varscan2
- RTEL1 | c.2226C>T p.I742= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV100542642; called by muse, mutect2
- SCN9A | c.5052T>C p.F1684= (on ENST00000303354; = p.F1673= on NM_002977.3) | Silent (SNP) | VAF 101/388 reads (26%) | catalogued as COSV100313642; called by muse, mutect2, varscan2
- SH3RF2 | c.1728C>T p.L576= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as COSV100767925; called by muse, mutect2, varscan2
- SLC12A1 | c.2577C>T p.G859= | Silent (SNP) | VAF 71/214 reads (33%) | catalogued as rs752794098, COSV101119093; called by muse, mutect2, varscan2
- SLC23A2 | c.630C>T p.P210= | Silent (SNP) | VAF 59/264 reads (22%) | catalogued as COSV100595161; called by muse, mutect2, varscan2
- SLC5A12 | c.324C>T p.I108= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99745302; called by muse, mutect2, varscan2
- SORL1 | c.4896C>G p.L1632= | Silent (SNP) | VAF 34/458 reads (7%) | catalogued as COSV52757867; called by muse, mutect2
- SPATA31D1 | c.4356G>A p.E1452= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV100782937, COSV100782938; called by muse, mutect2, varscan2
- STXBP5 | c.2721G>A p.Q907= (on ENST00000321680 / NM_001127715.2; = p.Q871= on NM_139244.4) | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99470717; called by muse, mutect2, varscan2
- SYNJ1 | c.4431C>T p.I1477= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100449528; called by muse, mutect2, varscan2
- TNRC18 | c.7377G>A p.E2459= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV100079036; called by muse, mutect2, varscan2
- TRIM49 | c.1290A>G p.L430= | Silent (SNP) | VAF 32/208 reads (15%) | catalogued as COSV100316187; called by muse, mutect2, varscan2
- TTC16 | c.781C>T p.L261= | Silent (SNP) | VAF 43/65 reads (66%) | catalogued as COSV64777556; called by muse, mutect2, varscan2
- UNC5D | c.2073G>T p.L691= | Silent (SNP) | VAF 32/358 reads (9%) | catalogued as COSV99777582; called by muse, mutect2
- XIRP2 | c.9378G>A p.V3126= (on ENST00000628543; = p.V3301= on NM_152381.6) | Silent (SNP) | VAF 59/217 reads (27%) | catalogued as COSV99745795; called by muse, mutect2, varscan2
- ZBED9 | c.2163T>G p.P721= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV101509231, COSV101509347; called by muse, mutect2, varscan2
- ZNF385B | c.489C>A p.S163= | Silent (SNP) | VAF 82/217 reads (38%) | catalogued as COSV100416275; called by muse, mutect2, varscan2
- ZNF404 | c.1581A>G p.E527= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100182717; called by muse, mutect2, varscan2
- AC073310.1 | n.342C>T | RNA (SNP) | VAF 150/318 reads (47%) | catalogued as rs1450185589; called by muse, mutect2, varscan2
- DST | c.4297-4864G>A | Intron (SNP) | VAF 59/202 reads (29%) | catalogued as COSV99758590; called by muse, mutect2, varscan2
- ENGASE | c.*629G>C | 3'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445885 G>T | 3'Flank (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1210C>T | RNA (SNP) | VAF 15/83 reads (18%) | catalogued as rs367837935; called by muse, varscan2
- MAP4 | c.1999+5663G>A | Intron (SNP) | VAF 7/175 reads (4%) | catalogued as COSV99275952; called by muse, mutect2
- MYB | c.1203+1156A>T | Intron (SNP) | VAF 40/158 reads (25%) | catalogued as COSV100215050; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442689 C>T | 3'Flank (SNP) | VAF 26/58 reads (45%) | catalogued as rs534972548, COSV100679204; called by muse, mutect2, varscan2
- OFCC1 | n.448G>C | RNA (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- OR2W5 | n.895G>T | RNA (SNP) | VAF 85/244 reads (35%) | called by muse, mutect2, varscan2
- OR52A4P | n.947G>T | RNA (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- PHACTR1 | c.664+2137G>A | Intron (SNP) | VAF 24/302 reads (8%) | catalogued as COSV100278309; called by muse, mutect2
- SYTL2 | c.1459+2634G>A | Intron (SNP) | VAF 42/136 reads (31%) | catalogued as COSV100314656; called by muse, mutect2, varscan2
- XIRP2 | c.*897A>G | 3'UTR (SNP) | VAF 21/85 reads (25%) | catalogued as COSV99745798; called by muse, mutect2, varscan2
